CCDI case PBCIJZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cd96d79f-a397-4fbe-97ec-f91c689845b4

Demographics
Sex at birth: female; Race: american indian or alaska native.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 2.0 years (730 days).

Biospecimens (3 samples)
- Sample 0DSWYQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSWZ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
